Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A65G, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A65G-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC LYMPH NODES, LYMPHADENECTOMY -

- A. SIX BENIGN LYMPH NODES (0/6).
- B. NO EVIDENCE OF MALIGNANCY.

PART 2: LEFT PELVIC LYMPH NODES, LYMPHADENECTOMY -

- A. EIGHTEEN BENIGN LYMPH NODES (0/18).
- B. NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 5 = 8 WITH A TERTIARY GLEASON PATTERN 4 CARCINOMA COMPONENT WITH EXTRACELLULAR MUCIN, INVOLVING BOTH RIGHT AND LEFT LOBES OF THE PROSTATE GLAND, EXTENDING FROM THE APEX THROUGH THE BASE. GLEASON PATTERNS 4/5 CARCINOMA COMPONENTS COMPRISE APPROXIMATELY 25% OF THE EXAMINED TUMOR VOLUME (SLIDES 3BB, 3DD, 3FF, 3HH, AND 3KK).
- B. MAXIMAL TUMOR DIAMETER IS 1.3 CM IN A HISTOLOGIC SECTION (SLIDE 3DD).
- C. CARCINOMA COMPRISES APPROXIMATELY 10% OF THE EXAMINED PROSTATE GLAND VOLUME.
- D. CARCINOMA IS CONFINED TO THE PROSTATE GLAND, WITH NO EXTRACAPSULAR EXTENSION IDENTIFIED.
- E. FOCAL CARCINOMATOUS PERINEURAL INVASION IS IDENTIFIED (SLIDE 3U).
- F. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. FOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA, TUFTED TYPE (SLIDES 3D-3Y).
- H. ALL SURGICAL RESECTION MARGINS ARE BENIGN.
- I. BENIGN BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA.
- J. NON-NEOPLASTIC PROSTATE TISSUE WITH FOCAL GLANDULAR ATROPHY AND FOCAL DYSTROPHIC CALCIFICATIONS.
- K. TNM PATHOLOGIC STAGE: T2c, N0, MX.
- L. HISTOLOGIC GRADE: G3-4 (See synoptic).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 6.8
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 5
GLEASON SUM SCORE: 8
GLEASON 4/5 PERCENTAGE: 25%
WEIGHT OF PROSTATE: 36.55gm
TUMOR SIZE: Maximum dimension: 1.3 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - NOS
EXTRAPROSTATIC EXTENSION: No
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: No
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 24
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT2c
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

check ICD-O-3
Adenocarcinoma, acinar 8140/3
with Adenocarcinoma NOS 8140/3
State Prostate NOS C61.9
JW 5/16/13

PATIENT HISTORY:

The patient is a year-old white man with a serum PSA value of 6.8 ng/mL. He had a recent prostate needle biopsy performed on this biopsy revealed prostatic adenocarcinoma in the left apex, left mid, and left base (Gleason score 3+3=6).

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy and bilateral pelvic lymphadenectomy.

Prior Malignant History		☒

Source: NCI Genomic Data Commons file c42a4a49-9b03-42e6-ab24-bd765d8ec75a (TCGA-EJ-A65G.A04673B5-5B72-4D0F-B12A-BC2663A2855B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).